Somatic mutation profile of tumor specimen BA2426D (aliquot aq-BA2426D) from BEATAML1.0 case 2511, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.2 years (22,729 days).
Specimen BA2426D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2640b4ab-4199-426c-8426-c733f74fb854.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2179D (Solid Tissue Normal), aliquot aq-BA2179D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d7dc2cf-6b8f-4eaf-b74c-b5b7de9821b4

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 5, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL13B | c.761C>A p.T254K (on ENST00000394222 / NM_001174150.2; = p.T147K on NM_144996.4) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV57397450; called by muse, mutect2
- GRIN2B | c.3499G>A p.V1167I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1042339; ClinVar: uncertain significance; called by muse, varscan2
- BRD9 | c.1526-1G>A p.X509_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- EEA1 | c.3654G>T p.L1218F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.356); called by muse, mutect2
- NGLY1 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2
- OTOGL | c.4741C>A p.Q1581K (on ENST00000547103; = p.Q1572K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2
- EVX1 | c.453C>A p.G151= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- FCGRT | c.612C>A p.S204= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- GPR52 | c.228C>A p.T76= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- PCBP3 | c.321C>T p.I107= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1419750044, COSV68406486; called by muse, mutect2, varscan2
- ZNF142 | c.4098G>T p.G1366= (on ENST00000411696 / NM_001379660.1; = p.G1166= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs1254043275; called by muse, mutect2
- SYDE2 | c.*1G>T | 3'UTR (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
